Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A1O0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A1O0-01A (Primary Tumor).

[page 1 of 6]
100.0-3

Adenocarcinoma, endometrioid and clear cell types 8380/3

Site: Endometrium C54.1

2/24/11 *lu*

Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

- A. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: Endometrial adenocarcinoma, mixed endometrioid and clear cell types (90% endometrioid, 10% clear cell), FIGO grade 3 (of 3) is identified forming a mass (3.6 x 2.9 x 2.0 cm) located in the posterior uterine wall. The tumor invades 0.1 cm into the myometrium (total myometrial thickness, 1.7 cm) and does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. The bilateral ovaries and fallopian tubes are not involved.
- B. Peritoneum, abdominal wall, biopsy: Negative for tumor.
- C. Lymph nodes, right pelvic, lymphadenectomy: Multiple (21) right pelvic lymph nodes are negative for tumor.
- D. Lymph nodes, left pelvic, lymphadenectomy: Multiple (17) left pelvic lymph nodes are negative for tumor.
- E. Omentum, omentectomy: Negative for tumor.
- F. Lymph nodes, left para-aortic, lymphadenectomy: Multiple (5) left para-aortic lymph nodes are negative for tumor.
- G. Gonadal vessels, left, biopsy: Negative for tumor.

[page 2 of 6]
H. Lymph nodes, right para-aortic, lymphadenectomy:
Multiple (4)
right para-aortic lymph nodes are negative for tumor.

I. Gonadal vessels, right, biopsy: Negative for tumor.

J. Peritoneum, cul de sac, biopsy: Negative for tumor.

K. Peritoneum, bladder, biopsy: Negative for tumor.

L. Peritoneum, left colic gutter, biopsy: Negative for tumor.

M. Peritoneum, right colic gutter, biopsy: Negative for tumor.

N. Peritoneum, right diaphragm, biopsy: Negative for tumor.

O. Peritoneum, left pelvic sidewall, biopsy: Negative for tumor.

P. Peritoneum, right pelvic sidewall, biopsy: Negative for tumor.

Q. Peritoneum, small bowel mesentery, biopsy: Negative for tumor.

R. Peritoneum, large bowel mesentery, biopsy: Negative for tumor.

S. Peritoneum, small bowel serosa, biopsy: Negative for tumor.

T. Peritoneum, large bowel serosa, biopsy: Negative for tumor.

With available surgical material [AJCC pT1aN0] (7th edition, 2010).

PRELIMINARY FROZEN SECTION CONSULTATION:

A. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and

[page 3 of 6]
bilateral salpingo-oophorectomy: Endometrial adenocarcinoma, endometrioid type, FIGO grade 3 (of 3). No definitive myometrial invasion identified. Hold over to evaluate myometrial invasion and histologic subtype.

B. Peritoneum, abdominal wall, biopsy: Negative for tumor.

C. Lymph nodes, right pelvic, lymphadenectomy: Multiple (21) right pelvic lymph nodes are negative for tumor.

E. Omentum, omentectomy: Negative for tumor.

H. Lymph nodes, right para-aortic, lymphadenectomy: Multiple (4) right para-aortic lymph nodes are negative for tumor.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, right and left fallopian tubes and ovaries" is a 101.2 gram uterus with attached bilateral tubes and ovaries. The uterine serosa is smooth. There is a 3.6 x 2.9 x 2.0 cm exophytic soft tan mass in the posterior wall of the endometrial cavity without gross invasion. The myometrial thickness is 1.7 cm. There are multiple (2) intramural and subserosal leiomyomas (1.5 cm and 2.2 cm in greatest dimension). There is a 2.6 x 1.7 x 1.0 cm right ovary with a smooth outer surface and a solid cut surface with a 10.2 x 0.8 cm right fallopian tube which is unremarkable. There is a 1.8 x 1.5 x 0.7 cm left ovary with a smooth outer surface and a solid cut surface with a 5.5 x 0.5 cm left fallopian tube which is unremarkable. Representative sections

[page 4 of 6]
submitted.

B. Received fresh labeled "abdominal wall" is a 0.7 x 0.6 x 0.4 cm fragment of yellow-tan soft tissue. All submitted.

C. Received fresh labeled "right pelvic nodes" is an 11.0 x 8.0 x 2.0 cm aggregate of adipose tissue and lymph nodes. All lymph nodes submitted.

D. Received fresh labeled "left pelvic nodes" is a 10.0 x 8.0 x 2.0 cm aggregate of adipose tissue and lymph nodes. All lymph nodes submitted.

E. Received fresh labeled "omentum" is a 71.8 x 17.5 x 3.0 cm portion of omentum. No masses are identified grossly. Lymph nodes

are not identified. Representative sections submitted.

F. Received fresh labeled "left para-aortic lymph nodes" is a 4.0 x 3.6 x 1.5 cm aggregate of adipose tissue and lymph nodes. All lymph nodes submitted.

G. Received fresh labeled "left gonadal vessels" is an 8.5 cm in length by 0.3 cm in diameter portion of unremarkable blood vessel. A representative section is submitted.

H. Received fresh labeled "right para-aortic lymph nodes" is a 4.0 x 3.0 x 1.5 cm aggregate of adipose tissue and lymph nodes. All lymph nodes submitted.

I. Received fresh labeled "right gonadal vessels" is a 4.7 cm in length by 0.6 cm in diameter portion of unremarkable blood vessel. A representative section is submitted.

[page 5 of 6]
J. Received fresh labeled "cul de sac" is a 0.7 x 0.7 x 0.3 cm aggregate of tan yellow soft tissue which is entirely submitted.

K. Received fresh labeled "bladder peritoneum" is a 0.4 x 0.3 x 0.2 cm aggregate of tan yellow soft tissue which is entirely submitted.

L. Received fresh labeled "left colic gutter" is a 2.4 x 1.1 x 0.7 cm aggregate of tan yellow soft tissue which is entirely submitted.

M. Received fresh labeled "right colic gutter" is a 0.7 x 0.7 x 0.3 cm aggregate of tan yellow soft tissue which is entirely submitted.

N. Received fresh labeled "right diaphragm" is a 0.9 x 0.9 x 0.3 cm aggregate of tan yellow soft tissue which is entirely submitted.

O. Received fresh labeled "left pelvic sidewall" is a 0.3 x 0.3 x 0.3 cm aggregate of tan yellow soft tissue which is entirely submitted.

P. Received fresh labeled "right pelvic sidewall" is a 0.4 x 0.4 x 0.2 cm aggregate of tan yellow soft tissue which is entirely submitted.

Q. Received fresh labeled "small bowel mesentery" is a 1.1 x 0.7 x 0.6 cm aggregate of tan yellow soft tissue which is entirely submitted.

[page 6 of 6]
R. Received fresh labeled "large bowel mesentery" is a 0.9 x 0.7 x

0.3 cm aggregate of tan yellow soft tissue which is entirely submitted.

S. Received fresh labeled "small bowel serosa" is a 0.3 x 0.3 x 0.2

cm aggregate of tan yellow soft tissue which is entirely submitted.

T. Received fresh labeled "large bowel serosa" is a 0.2 x 0.2 x 0.2

cm aggregate of tan yellow soft tissue which is entirely submitted.

Dual/Synchronous Imaging Noted		/

Source: NCI Genomic Data Commons file b86566ae-9e61-4512-97c7-29eda47bfe60 (TCGA-D1-A1O0.2F5CADA5-176C-4B9D-9660-53BE86B1CD39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).